Gene-level copy-number profile of tumor specimen TCGA-QK-A8Z7-01A from TCGA case TCGA-QK-A8Z7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Age at diagnosis: 59.4 years (21,711 days).
Specimen TCGA-QK-A8Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.cbfcf1a0-ed8a-4c59-9b5a-ad53846b7d79.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QK-A8Z7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/82148d11-2c03-4c38-86f9-2627166508e8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 12; copy number 2: 13,618; copy number 3: 15,413; copy number 4: 19,056; copy number 5: 6,123; copy number 6: 3,170; copy number 7: 1,245; copy number 8: 56; copy number 9: 406; copy number 10: 153; copy number 11: 264; copy number 12: 174; copy number 13: 26; copy number 27: 59; copy number 44: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-QK-A8Z7-01A-11D-A390-01): tumor purity 0.7, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes: RNU6-904P, RPS16P3.
- chr9:21,967,752–21,995,301, 1 gene (within-gene range 0–2): CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,109 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,023,918–122,887,691, 75 genes, copy number 10–11 (within-gene range 3–11) (broad region; genes not listed).
- chr3:147,590,996–198,222,513, 908 genes, copy number 9–13 (broad region; genes not listed).
- chr6:124,962,545–125,445,193, 5 genes, copy number 9 (within-gene range 5–9): RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1.
- chr7:54,185,071–56,687,366, 86 genes, copy number 27–44 (broad region; genes not listed).
- chr9:35,791,591–36,830,456, 32 genes, copy number 10 (within-gene range 8–10): NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL442063.1, AL450267.2, MIR4475.
- chr9:36,856,555–36,893,531, 3 genes, copy number 10: AL450267.1, MIR4540, MIR4476.

Autosomal genes at a single copy (total copy number 1): 12. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
